Gene-level copy-number profile of tumor specimen HCM-CSHL-0625-C18-06A from HCMI case HCM-CSHL-0625-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 66.6 years (24,332 days).
Specimen HCM-CSHL-0625-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dba1218d-9ca2-4961-842c-b96c86193599.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0625-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/f6c79edf-2325-4786-8e25-a8d63a8a33a4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 362; copy number 1: 1,292; copy number 2: 15,246; copy number 3: 11,751; copy number 4: 28,363; copy number 5: 239; copy number 6: 906; copy number 7: 48; copy number 8: 8; copy number 9: 10; copy number 11: 592; copy number 13: 83.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr6:29,124,210–29,182,445, 4 genes: AL645937.2, AL645937.1, OR2J2, OR2J4P.
- chr8:7,836,436–8,049,267, 17 genes: DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–2): MIR1233-2.
- chr17:18,450,244–18,475,920, 4 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr18:36,297,714–36,780,055, 2 genes (within-gene range 0–2): FHOD3, AC055840.1.
- chr18:49,116,301–49,126,479, 1 gene (within-gene range 0–2): AC016866.2.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–3): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 685 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,257,664–42,063,969, 310 genes, copy number 11 (broad region; genes not listed).
- chr20:43,652,523–60,083,872, 375 genes, copy number 9–13 (within-gene range 9–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
